Somatic mutation profile of tumor specimen TCGA-A5-A0GP-01A (aliquot TCGA-A5-A0GP-01A-11W-A062-09) from TCGA case TCGA-A5-A0GP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 58.5 years (21,365 days).
Specimen TCGA-A5-A0GP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 316a74fb-edfe-4247-87a2-00e30187cefc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0GP-10A (Blood Derived Normal), aliquot TCGA-A5-A0GP-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b797c7b-ab56-4a0b-bf0b-7cfa6ef28539

The open-access MAF lists 1,768 somatic variants for this specimen: 1,360 protein-altering or splice-affecting, 361 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,175, Silent 361, Nonsense Mutation 152, Intron 20, Splice Site 14, 3'UTR 10, Frame Shift Ins 10, RNA 8, Splice Region 5, 5'Flank 5, 5'UTR 3, Frame Shift Del 2.

Variants (750 of 1,768; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 94/286 reads (33%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLCN5 | c.2152C>T p.R718* | Nonsense Mutation (SNP) | VAF 51/157 reads (32%) | catalogued as rs797044814, CM033762, COSV56585339; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTCF | c.1342C>T p.R448* | Nonsense Mutation (SNP) | VAF 56/187 reads (30%) | hotspot (GDC flag); catalogued as rs769948988, COSV50461776; called by muse, mutect2, varscan2
- DMD | c.2317A>G p.K773E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs128626244, CM098378, CM940349, COSV63771096; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYNC2H1 | c.1306G>T p.E436* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as rs371011047, CM133140, COSV62085201; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 95/302 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 15/49 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 93/259 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs3218713, CM910268, COSV62516493; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.238A>C p.T80P | Missense Mutation (SNP) | VAF 27/90 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960056, COSV67960150; called by muse, mutect2, varscan2
- NSD1 | c.6050G>A p.R2017Q | Missense Mutation (SNP) | VAF 105/311 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587784177, CM030081, COSV61777421, COSV61786250; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PGM1 | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 69/197 reads (35%) | catalogued as rs770066171, COSV64300954; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 47/188 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 49/128 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PLCE1 | c.4451C>T p.S1484L | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912605, CM066177, COSV53350732, COSV99593752; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 82/264 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519945, COSV57676103, COSV57677068, COSV57683938; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 114/293 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 98/288 reads (34%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- RTKN2 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 26/92 reads (28%) | hotspot (GDC flag); catalogued as rs772033296, COSV65679700, COSV65679972; called by muse, mutect2, varscan2
- SCN10A | c.3910G>A p.A1304T | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs142173735, CM1211117, COSV71862086; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SEC24D | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148676365; ClinVar: pathogenic; called by muse, mutect2
- TTN | c.85447G>T p.E28483* (on ENST00000591111; = p.E21059* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 28/72 reads (39%) | catalogued as rs1553539995, COSV59918596, COSV60071705; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.3127G>A p.A1043T | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59389219; called by muse, mutect2, varscan2
- AASDH | c.345A>C p.Q115H | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV99221428; called by muse, mutect2
- AASDHPPT | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.676); catalogued as rs761620246, COSV53789640; called by muse, mutect2, varscan2
- AASS | c.1319T>G p.F440C | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV62790796; called by muse, mutect2, varscan2
- ABCA1 | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV66059092, COSV66060190; called by muse, mutect2, varscan2
- ABCA10 | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 64/204 reads (31%) | catalogued as COSV52221811; called by muse, mutect2, varscan2
- ABCA13 | c.5914A>C p.N1972H | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as COSV70034158; called by muse, mutect2, varscan2
- ABCA13 | c.10310A>G p.Q3437R | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs749333345, COSV71291072; called by muse, mutect2, varscan2
- ABCA13 | c.13570G>A p.A4524T | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1163099421, COSV68948669; called by muse, mutect2, varscan2
- ABCA6 | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.022); catalogued as rs781249897, COSV52638284; called by muse, mutect2, varscan2
- ABCA8 | c.110C>A p.S37* | Nonsense Mutation (SNP) | VAF 33/103 reads (32%) | catalogued as rs1441396195, COSV52206136; called by muse, mutect2, varscan2
- ABCB5 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 78/241 reads (32%) | catalogued as COSV51714014; called by muse, mutect2, varscan2
- ABCC12 | c.2784G>T p.E928D | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.649); catalogued as COSV60915275; called by muse, mutect2, varscan2
- ABCC2 | c.2727T>G p.F909L | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64987100; called by muse, mutect2, varscan2
- ABHD8 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as COSV99917289; called by muse, mutect2
- ABL1 | c.214T>G p.F72V | Missense Mutation (SNP) | VAF 86/265 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59335545; called by muse, mutect2, varscan2
- AC134980.2 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs770220391, COSV60907181; called by mutect2, varscan2
- ACHE | c.287T>C p.F96S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV53819309; called by muse, mutect2, varscan2
- ACSL3 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 19/326 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1177812495, COSV62483596, COSV62485156; called by muse, mutect2
- ACSM1 | c.405G>A p.G135= | Splice Region (SNP) | VAF 52/160 reads (33%) | catalogued as COSV54632881; called by muse, mutect2, varscan2
- ACSM2A | c.533G>T p.R178I (on ENST00000219054; = p.R99I on NM_001308169.2) | Missense Mutation (SNP) | VAF 176/577 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs185396407, COSV54586771; called by muse, mutect2, varscan2
- ADAMTS17 | c.3152G>A p.R1051Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.494); catalogued as rs747317920, COSV51485991; called by muse, mutect2, varscan2
- ADAMTS19 | c.2104C>G p.Q702E | Missense Mutation (SNP) | VAF 52/232 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50764328; called by muse, varscan2
- ADAMTS20 | c.3729G>T p.E1243D | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.331); catalogued as COSV67134711; called by muse, mutect2, varscan2
- ADAMTS20 | c.578C>A p.S193Y | Missense Mutation (SNP) | VAF 69/226 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs896864581, COSV67130605, COSV67134713; called by muse, mutect2, varscan2
- ADAMTS3 | c.2695T>C p.C899R | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54396010; called by muse, mutect2, varscan2
- ADCY5 | c.2309T>C p.L770P | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV59200515; called by muse, mutect2, varscan2
- ADCY8 | c.3242C>A p.S1081* | Nonsense Mutation (SNP) | VAF 19/64 reads (30%) | catalogued as COSV53915281; called by muse, mutect2, varscan2
- ADCY9 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV53572158; called by muse, mutect2, varscan2
- ADGRE2 | c.246C>A p.F82L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1440588897, COSV100216142; called by muse, mutect2
- ADGRF2 | c.1619C>G p.A540G (on ENST00000296862 / NM_001368115.2; = p.A472G on NM_153839.7) | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.324); catalogued as COSV57289123, COSV99731349; called by muse, mutect2
- ADGRG4 | c.3848C>A p.S1283Y | Missense Mutation (SNP) | VAF 191/591 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs377239456, COSV54957590, COSV54966049; called by muse, mutect2, varscan2
- ADGRG4 | c.7361A>C p.K2454T | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as COSV54961097; called by muse, mutect2, varscan2
- ADGRG7 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs779095865, COSV56293281; called by muse, mutect2, varscan2
- ADGRL2 | c.3403C>T p.R1135C (on ENST00000370717 / NM_001366005.1; = p.R1122C on NM_012302.4) | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1014195159, COSV54655645; called by muse, mutect2, varscan2
- ADGRL4 | c.730A>C p.T244P | Missense Mutation (SNP) | VAF 100/320 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV66062917; called by muse, mutect2, varscan2
- ADGRV1 | c.2101G>T p.A701S | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV67980755, COSV67989591; called by muse, mutect2, varscan2
- ADGRV1 | c.5156C>T p.A1719V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.155); catalogued as rs376126357; called by muse, mutect2, varscan2
- AFG1L | c.348A>C p.E116D | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV64556700; called by muse, mutect2, varscan2
- AGPS | c.790-1G>A p.X264_splice | Splice Site (SNP) | VAF 44/135 reads (33%) | catalogued as COSV51566223, COSV51568590; called by muse, mutect2, varscan2
- AGT | c.226A>G p.T76A | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs763626003, COSV64185001; called by muse, mutect2, varscan2
- AKAP6 | c.1128C>A p.C376* | Nonsense Mutation (SNP) | VAF 98/306 reads (32%) | catalogued as COSV55209630, COSV99801703; called by muse, mutect2
- AKAP6 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 78/218 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs745838442, COSV55220970; called by muse, mutect2, varscan2
- ALMS1 | c.7932T>G p.N2644K | Missense Mutation (SNP) | VAF 135/421 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52514365; called by muse, mutect2, varscan2
- ALPG | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs568507509, COSV54964676; called by muse, mutect2
- ALPK1 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749235785, COSV51587806; called by muse, mutect2, varscan2
- AMER1 | c.1524C>A p.F508L | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); catalogued as rs1288332581, COSV57659044, COSV57663326; called by muse, mutect2, varscan2
- AMPH | c.939G>T p.K313N | Missense Mutation (SNP) | VAF 77/251 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57748328; called by muse, mutect2, varscan2
- AMPH | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781682680, COSV57737654; called by muse, mutect2, varscan2
- ANAPC1 | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs772338494, COSV61977492; called by muse, mutect2, varscan2
- ANGPT1 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV52439970; called by muse, mutect2, varscan2
- ANK3 | c.5531C>A p.S1844* | Nonsense Mutation (SNP) | VAF 90/261 reads (34%) | catalogued as COSV55067486; called by muse, mutect2, varscan2
- ANKFN1 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 47/138 reads (34%) | catalogued as rs1049623576, COSV59452466; called by muse, mutect2, varscan2
- ANKRD17 | c.429A>T p.E143D | Missense Mutation (SNP) | VAF 79/277 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.036); catalogued as COSV58223631, COSV58227492; called by muse, mutect2, varscan2
- ANKRD27 | c.1018T>C p.F340L | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs1204726070, COSV60133371; called by muse, mutect2, varscan2
- ANKRD28 | c.2203C>A p.L735I | Missense Mutation (SNP) | VAF 88/237 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV67519020; called by muse, mutect2, varscan2
- ANKRD30A | c.3634A>C p.I1212L (on ENST00000611781; = p.I1156L on NM_052997.2) | Missense Mutation (SNP) | VAF 78/227 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV64614789; called by muse, mutect2, varscan2
- ANKS1B | c.3191C>T p.A1064V (on ENST00000547776 / NM_152788.4; = p.A230V on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59121799; called by muse, mutect2, varscan2
- ANLN | c.2621A>G p.D874G | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs752097628, COSV56077641; called by muse, mutect2, varscan2
- ANO3 | c.1299T>G p.I433M | Missense Mutation (SNP) | VAF 135/433 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56779987; called by muse, mutect2, varscan2
- AP002512.3 | c.581C>A p.T194N | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as COSV54405568; called by muse, mutect2
- AP3M2 | c.362T>C p.F121S | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs959631133, COSV51529632; called by muse, mutect2, varscan2
- APBB1IP | c.326C>A p.S109Y | Missense Mutation (SNP) | VAF 73/240 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV63302445; called by muse, mutect2, varscan2
- APBB1IP | c.870G>T p.M290I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV66133896; called by muse, mutect2, varscan2
- APC | c.2875T>C p.S959P | Missense Mutation (SNP) | VAF 80/190 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV57358793; called by muse, mutect2, varscan2
- APC | c.3227C>T p.P1076L | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.247); catalogued as rs766394131, COSV57358799, COSV57393256, COSV99966770; called by muse, mutect2, varscan2
- APCDD1 | c.1364G>T p.R455I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62372770; called by muse, mutect2, varscan2
- APEX2 | c.290A>G p.E97G | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66624227; called by muse, mutect2, varscan2
- API5 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV66633664; called by muse, mutect2, varscan2
- APLP1 | c.1394G>A p.G465D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV55705034; called by muse, mutect2, varscan2
- APOB | c.11607C>A p.F3869L | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.065); catalogued as COSV51942607, COSV51954942; called by muse, mutect2, varscan2
- APOB | c.5722G>A p.D1908N | Missense Mutation (SNP) | VAF 118/402 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as rs751368655, COSV51942614, COSV51953646; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.4742T>C p.F1581S | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV99266136; called by muse, mutect2
- APOBR | c.1970G>A p.R657Q (on ENST00000431282; = p.R666Q on NM_018690.4) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143668661, COSV60491951; called by muse, mutect2
- APOL1 | c.224T>C p.F75S | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59869388; called by muse, mutect2, varscan2
- AQR | c.3053G>A p.R1018Q | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370660482, COSV50031222; called by muse, mutect2, varscan2
- ARCN1 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1555076137, COSV50616086; called by muse, mutect2, varscan2
- ARHGAP11B | c.765A>C p.K255N | Missense Mutation (SNP) | VAF 28/492 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV101451801; called by muse, mutect2
- ARHGAP18 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 14/119 reads (12%) | catalogued as COSV63765172, COSV63766640; called by muse, mutect2, varscan2
- ARHGAP4 | c.818A>C p.D273A | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV63133061; called by muse, mutect2, varscan2
- ARHGAP44 | c.610T>G p.F204V | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99310916; called by muse, mutect2
- ARHGEF7 | c.331G>A p.D111N (on ENST00000375741 / NM_001113511.2; = p.D90N on NM_145735.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.975); catalogued as COSV54546585; called by muse, mutect2, varscan2
- ARID3C | c.1123G>T p.G375W | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM148096, COSV52406957; called by muse, mutect2, varscan2
- ARID5B | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 192/618 reads (31%) | catalogued as COSV54414394, COSV54414704, COSV54420304; called by muse, mutect2, varscan2
- ARID5B | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 82/230 reads (36%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs374377066, COSV54429955; called by muse, mutect2, varscan2
- ARL6 | c.475A>C p.I159L | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV60118082; called by muse, mutect2, varscan2
- ARMC4 | c.1825C>T p.R609C | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as rs937112850, COSV59460405; called by muse, mutect2, varscan2
- ARMCX2 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100168196; called by muse, mutect2
- ARMCX2 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs782811435, COSV57529832; called by muse, mutect2, varscan2
- ASB5 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 43/142 reads (30%) | catalogued as COSV56668461, COSV56670474; called by muse, mutect2, varscan2
- ASCC3 | c.4423T>G p.F1475V | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100976616; called by muse, mutect2
- ASH1L | c.7351G>T p.E2451* (on ENST00000368346 / NM_001366177.2; = p.E2446* on NM_018489.3) | Nonsense Mutation (SNP) | VAF 42/146 reads (29%) | catalogued as COSV100853475; called by muse, mutect2
- ASPM | c.8917G>T p.E2973* | Nonsense Mutation (SNP) | VAF 86/324 reads (27%) | catalogued as COSV54124439; called by muse, mutect2, varscan2
- ASPM | c.415A>C p.N139H | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); catalogued as COSV54133273; called by muse, mutect2, varscan2
- ASPN | c.1014G>T p.K338N | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100978626; called by muse, mutect2
- ASTN1 | c.2534T>C p.F845S | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56075582; called by muse, mutect2, varscan2
- ASZ1 | c.138G>T p.K46N | Missense Mutation (SNP) | VAF 78/264 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs202243868, COSV52914448; called by muse, mutect2, varscan2
- ATAD2 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54879779; called by muse, mutect2, varscan2
- ATAD2B | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as rs1029580293, COSV53201977; called by muse, mutect2, varscan2
- ATF6 | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV63408434; called by muse, mutect2, varscan2
- ATG2B | c.2941A>C p.N981H | Missense Mutation (SNP) | VAF 61/215 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); catalogued as COSV63424219; called by muse, mutect2, varscan2
- ATM | c.5347G>T p.E1783* | Nonsense Mutation (SNP) | VAF 65/207 reads (31%) | catalogued as COSV53755736; called by muse, mutect2, varscan2
- ATM | c.6417A>C p.E2139D | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV53755760; called by muse, mutect2, varscan2
- ATM | c.8049A>G p.I2683M | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs1292192410, COSV53755785; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATMIN | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.152); catalogued as rs1295601529, COSV55146747; called by muse, mutect2, varscan2
- ATP10A | c.3263T>C p.M1088T | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs768985885, COSV63520079; called by muse, mutect2, varscan2
- ATP11B | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 113/345 reads (33%) | catalogued as rs773928297, COSV60029578; called by muse, mutect2, varscan2
- ATP11C | c.2509A>C p.K837Q | Missense Mutation (SNP) | VAF 100/365 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV59568224; called by muse, mutect2, varscan2
- ATP11C | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.747); catalogued as rs1045378104, COSV59564141; called by muse, mutect2, varscan2
- ATP13A5 | c.1392G>T p.K464N | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as COSV60868389; called by muse, mutect2, varscan2
- ATP1A4 | c.2633T>C p.I878T | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV63627180; called by muse, mutect2, varscan2
- ATP1B4 | c.406C>A p.L136M (on ENST00000218008 / NM_001142447.3; = p.L132M on NM_012069.5) | Missense Mutation (SNP) | VAF 139/444 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); catalogued as COSV54311698; called by muse, mutect2, varscan2
- ATP2B2 | c.1783C>T p.R595C (on ENST00000352432; = p.R561C on NM_001683.5) | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776463160, COSV59494867; called by muse, mutect2, varscan2
- ATP4B | c.176T>C p.L59P | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs769896187, COSV58929334; called by muse, mutect2
- ATP7B | c.728T>G p.F243C | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99666566; called by muse, mutect2
- ATP8A2 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); catalogued as rs748812032, COSV54939414; called by muse, mutect2, varscan2
- ATP8B2 | c.213G>T p.K71N (on ENST00000672630; = p.K38N on NM_001005855.2) | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59247062; called by muse, mutect2, varscan2
- ATP8B2 | c.797G>A p.G266D (on ENST00000672630; = p.G233D on NM_001005855.2) | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59247079; called by muse, mutect2, varscan2
- ATRX | c.5135G>A p.G1712D | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100970771; called by muse, mutect2
- ATXN3L | c.859T>G p.F287V | Missense Mutation (SNP) | VAF 110/349 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66075974; called by muse, mutect2, varscan2
- AUTS2 | c.660C>T p.F220= | Splice Region (SNP) | VAF 94/257 reads (37%) | catalogued as rs766569162, COSV61397410; called by muse, mutect2, varscan2
- BANK1 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1428281031, COSV59850255; called by muse, mutect2
- BANK1 | c.2139G>T p.M713I | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV59842931, COSV59844962; called by muse, mutect2, varscan2
- BAZ1A | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 32/87 reads (37%) | catalogued as COSV62411008; called by muse, mutect2, varscan2
- BAZ2A | c.2298A>C p.E766D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV51639573; called by muse, mutect2, varscan2
- BAZ2B | c.5111T>G p.F1704C | Missense Mutation (SNP) | VAF 20/245 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV100600740; called by muse, mutect2
- BAZ2B | c.2237G>A p.R746H | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs991973729, COSV58597206, COSV58607198; called by muse, mutect2, varscan2
- BBS10 | c.1634C>T p.S545F | Missense Mutation (SNP) | VAF 112/300 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1221945074, COSV101283336, COSV67913304; called by muse, mutect2, varscan2
- BBS12 | c.916A>C p.K306Q | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.072); catalogued as COSV58562440; called by muse, mutect2, varscan2
- BBS9 | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV54175921; called by muse, mutect2, varscan2
- BCHE | c.1554G>T p.W518C | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100012685; called by muse, mutect2
- BCHE | c.1226G>T p.R409I | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100011916, COSV52259148; called by muse, mutect2, varscan2
- BCORL1 | c.1794C>A p.F598L | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as COSV54400351; called by muse, mutect2, varscan2
- BEND6 | c.81G>A p.M27I | Missense Mutation (SNP) | VAF 115/397 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66069458; called by muse, mutect2, varscan2
- BEST3 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.99); PolyPhen benign (0.272); catalogued as COSV58302552; called by muse, mutect2, varscan2
- BIRC6 | c.11698G>T p.E3900* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV70197254; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3198G>T p.E1066D | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV63244296; called by muse, mutect2, varscan2
- BMP3 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1435451372, COSV51081644; called by muse, mutect2, varscan2
- BMP5 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.895); catalogued as COSV63702143; called by muse, mutect2, varscan2
- BMPER | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs767955858, COSV51811720; called by muse, mutect2, varscan2
- BNC1 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.688); catalogued as rs146985300; called by muse, mutect2, varscan2
- BRD2 | c.2164G>A p.G722R | Missense Mutation (SNP) | VAF 91/321 reads (28%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.998); catalogued as rs1382338097, COSV66373908; called by muse, mutect2, varscan2
- BRWD3 | c.5174G>A p.R1725Q | Missense Mutation (SNP) | VAF 12/325 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); catalogued as COSV64743547, COSV64747346; called by muse, mutect2
- BSN | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs200764425; called by muse, varscan2
- BTAF1 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200229615, COSV56436282; called by muse, mutect2, varscan2
- C12orf40 | c.340A>C p.N114H | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV61134788; called by muse, mutect2, varscan2
- C12orf40 | c.1656G>T p.E552D | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as COSV61130021; called by muse, mutect2, varscan2
- C12orf50 | c.336A>C p.K112N | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV53896881; called by muse, mutect2, varscan2
- C12orf56 | c.1756G>T p.E586* (on ENST00000543942 / NM_001170633.2; = p.E426* on NM_001099676.3) | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as rs1360425650, COSV100399546; called by muse, mutect2
- C18orf25 | c.1064C>A p.S355Y | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV56367436; called by muse, mutect2, varscan2
- C1QTNF9B | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.234); catalogued as rs1388943191, COSV65944341; called by muse, mutect2, varscan2
- C1orf105 | c.247T>C p.C83R | Missense Mutation (SNP) | VAF 60/201 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62959607; called by muse, mutect2, varscan2
- C1orf141 | c.1076T>C p.I359T | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1475167164, COSV63992946; called by muse, mutect2, varscan2
- C4orf3 | c.161T>C p.F54S | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs767655670, COSV67581828; called by muse, mutect2, varscan2
- C7orf25 | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63273935; called by muse, mutect2, varscan2
- C7orf33 | c.299C>A p.S100Y | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.793); catalogued as COSV61023437; called by muse, mutect2, varscan2
- C7orf57 | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.795); catalogued as COSV62363279; called by muse, mutect2, varscan2
- CAAP1 | c.529A>C p.K177Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV61701101; called by muse, mutect2, varscan2
- CAAP1 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as rs1401125154, COSV100445211, COSV61701108; called by muse, mutect2, varscan2
- CAB39L | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 70/248 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.727); catalogued as COSV61714159; called by muse, mutect2, varscan2
- CACHD1 | c.3209C>T p.A1070V | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV51556427; called by muse, mutect2, varscan2
- CACNA1A | c.3971T>C p.V1324A | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV64203509; called by muse, mutect2, varscan2
- CACNA1D | c.4094C>T p.A1365V (on ENST00000350061 / NM_001128840.3; = p.A1385V on NM_000720.4) | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766073405, COSV55453962; called by muse, mutect2, varscan2
- CACNA2D1 | c.345A>C p.E115D | Missense Mutation (SNP) | VAF 70/272 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV62384298; called by muse, mutect2, varscan2
- CACNA2D4 | c.2680G>A p.D894N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs777701038, COSV54954338; called by muse, mutect2
- CACNG7 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.025); catalogued as rs553878683, COSV55815664; called by muse, mutect2, varscan2
- CAMTA1 | c.3944C>A p.S1315Y | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as COSV57911892; called by muse, mutect2, varscan2
- CARS1 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1385451769, COSV53460549; called by muse, mutect2
- CASP8 | c.538G>T p.E180* (on ENST00000432109 / NM_033355.3; = p.E212* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 15/480 reads (3%) | catalogued as COSV51861924; called by muse, mutect2
- CATSPER1 | c.2054C>T p.A685V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754677282, COSV56409532; called by muse, mutect2, varscan2
- CATSPERD | c.612T>G p.F204L | Missense Mutation (SNP) | VAF 124/349 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV67535682; called by muse, mutect2, varscan2
- CATSPERE | c.1258T>G p.F420V | Missense Mutation (SNP) | VAF 106/328 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV63679612; called by muse, mutect2, varscan2
- CBFA2T2 | c.729G>T p.E243D | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1230077240, COSV60074720; called by muse, mutect2, varscan2
- CBLN4 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV50352129, COSV50354495; called by muse, mutect2, varscan2
- CBX1 | c.135C>A p.F45L | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV56682209; called by muse, mutect2, varscan2
- CCAR2 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.15); catalogued as COSV51516025; called by muse, mutect2, varscan2
- CCDC122 | c.764T>A p.I255N | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71573713; called by muse, mutect2, varscan2
- CCDC136 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as COSV52801866; called by muse, mutect2, varscan2
- CCDC144A | c.509C>A p.S170* | Nonsense Mutation (SNP) | VAF 67/286 reads (23%) | catalogued as COSV60699858; called by muse, mutect2, varscan2
- CCDC146 | c.1580A>C p.K527T | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53551149; called by muse, mutect2, varscan2
- CCDC151 | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52952528; called by muse, mutect2, varscan2
- CCDC171 | c.2346G>T p.K782N | Missense Mutation (SNP) | VAF 112/324 reads (35%) | SIFT tolerated (0.79); PolyPhen benign (0.015); catalogued as COSV52646101; called by muse, mutect2, varscan2
- CCDC58 | c.273G>T p.K91N | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.037); catalogued as COSV52246643, COSV52247457; called by muse, mutect2, varscan2
- CCDC7 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 20/98 reads (20%) | catalogued as COSV53226367; called by muse, mutect2, varscan2
- CCDC7 | c.2207A>C p.E736A | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.845); catalogued as COSV56546212; called by muse, mutect2, varscan2
- CCDC89 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs775520786, COSV57034441; called by muse, mutect2, varscan2
- CCNB2 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55595993; called by muse, mutect2, varscan2
- CCNB2 | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 82/269 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs531597901, COSV55596186; called by muse, mutect2, varscan2
- CCNB3 | c.3205G>T p.E1069* | Nonsense Mutation (SNP) | VAF 45/167 reads (27%) | catalogued as COSV52075938; called by muse, mutect2, varscan2
- CD163L1 | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58013857; called by muse, mutect2, varscan2
- CD180 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs756692863, COSV56518845; called by muse, mutect2, varscan2
- CD1C | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 213/614 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs761108555, COSV63806922; called by muse, mutect2, varscan2
- CD8A | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.743); catalogued as COSV52158329; called by muse, mutect2, varscan2
- CDC27 | c.1846G>T p.E616* | Nonsense Mutation (SNP) | VAF 25/80 reads (31%) | catalogued as COSV50367727; called by muse, mutect2, varscan2
- CDCA7L | c.538C>A p.L180I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs770218756, COSV62258043; called by muse, mutect2, varscan2
- CDH12 | c.1371C>A p.F457L | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV66420807; called by muse, mutect2, varscan2
- CDH26 | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs763227887, COSV54849804; called by muse, mutect2, varscan2
- CDH9 | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50282585, COSV50393674; called by muse, mutect2, varscan2
- CDK17 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1435117026, COSV54128792; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 9/255 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1343728654, COSV62574034; called by muse, mutect2
- CDKL5 | c.421C>A p.L141I | Missense Mutation (SNP) | VAF 103/294 reads (35%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.311); catalogued as COSV66112123; called by muse, varscan2
- CDKL5 | c.1098C>A p.F366L | Missense Mutation (SNP) | VAF 168/473 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV66112126; called by muse, mutect2, varscan2
- CEMIP | c.1850A>C p.D617A | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54995906; called by muse, mutect2, varscan2
- CEMIP2 | c.2145A>G p.I715M | Missense Mutation (SNP) | VAF 70/241 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV65488174; called by muse, mutect2, varscan2
- CENATAC | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV57723184; called by muse, mutect2, varscan2
- CENPE | c.3140C>A p.S1047Y | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54379591; called by muse, mutect2, varscan2
- CENPF | c.3147G>T p.K1049N | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.139); catalogued as COSV65274818; called by muse, mutect2, varscan2
- CENPI | c.732C>A p.F244L | Missense Mutation (SNP) | VAF 199/617 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as COSV54501456, COSV54504070; called by muse, mutect2, varscan2
- CEP112 | c.1049C>A p.S350Y | Missense Mutation (SNP) | VAF 82/341 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV67142064; called by muse, mutect2, varscan2
- CEP44 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 7/146 reads (5%) | catalogued as rs1201754063; called by muse, mutect2
- CERS6 | c.641T>C p.V214A | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59832227; called by muse, mutect2, varscan2
- CFAP43 | c.2579T>G p.V860G | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53379324; called by muse, mutect2, varscan2
- CFAP47 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 53/272 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs780374404, COSV52880535, COSV52882723; called by muse, mutect2, varscan2
- CFAP47 | c.1772G>A p.R591Q | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750366401, COSV52887894, COSV52889098; called by muse, mutect2, varscan2
- CFAP58 | c.1958G>A p.R653K | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV63832678, COSV63834200, COSV63835828; called by muse, mutect2, varscan2
- CFHR5 | c.802A>G p.T268A | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV56824161; called by muse, mutect2, varscan2
- CFHR5 | c.1582A>C p.K528Q | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as COSV56824170; called by muse, mutect2, varscan2
- CGB3 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV62164561; called by muse, mutect2, varscan2
- CGN | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as rs758114153, COSV54971644; called by muse, mutect2, varscan2
- CGNL1 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55571064; called by muse, mutect2, varscan2
- CHI3L2 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs757716048, COSV63874352; called by muse, mutect2, varscan2
- CHIC1 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV65156624; called by muse, mutect2, varscan2
- CHP1 | c.329G>A p.S110N | Missense Mutation (SNP) | VAF 69/206 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV58157714; called by muse, mutect2, varscan2
- CIAO1 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV55531150; called by muse, mutect2, varscan2
- CKAP5 | c.3928C>T p.R1310C | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1165738671, COSV56366190; called by muse, mutect2, varscan2
- CKMT2 | c.1254A>C p.K418N | Missense Mutation (SNP) | VAF 73/240 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); catalogued as COSV54174035; called by muse, mutect2, varscan2
- CLDN18 | c.427C>A p.L143M | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV51737094; called by muse, mutect2, varscan2
- CLDN8 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.198); catalogued as rs757114600, COSV54525792; called by muse, mutect2, varscan2
- CLEC12A | c.543A>C p.K181N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV100429539; called by muse, mutect2
- CLIP1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 33/351 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs987429426, COSV100211881; called by muse, mutect2
- CLSPN | c.3247G>A p.V1083I | Missense Mutation (SNP) | VAF 28/442 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.035); catalogued as rs748432048, COSV99231060; called by muse, mutect2
- CMTM5 | c.78C>G p.D26E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV59306796; called by muse, mutect2, varscan2
- CMYA5 | c.1528G>T p.E510* | Nonsense Mutation (SNP) | VAF 48/860 reads (6%) | catalogued as COSV101484143; called by muse, mutect2
- CNOT4 | c.596T>C p.F199S | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59655042; called by muse, mutect2, varscan2
- CNOT6 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 26/89 reads (29%) | catalogued as COSV56161748, COSV56162327; called by muse, mutect2, varscan2
- CNTN1 | c.1376G>A p.S459N | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV61642079; called by muse, mutect2, varscan2
- CNTNAP2 | c.2471C>A p.S824Y | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV62169812; called by muse, mutect2, varscan2
- CNTNAP4 | c.2356C>T p.Q786* | Nonsense Mutation (SNP) | VAF 34/109 reads (31%) | catalogued as rs774086024, COSV56689743; called by muse, mutect2, varscan2
- CNTNAP5 | c.112C>A p.L38I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV101443687; called by muse, mutect2
- CNTNAP5 | c.3355C>A p.Q1119K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV70495748; called by muse, mutect2, varscan2
- COL11A2 | c.1136G>A p.R379Q (on ENST00000341947 / NM_080680.3; = p.R272Q on NM_080679.2) | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.642); catalogued as rs150429851; ClinVar: uncertain significance; called by muse, mutect2
- COL11A2 | c.778A>C p.N260H | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV59499135; called by muse, mutect2, varscan2
- COL4A2 | c.1291C>T p.R431* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as rs747324600, COSV64628826; called by muse, mutect2, varscan2
- COL4A3 | c.4924T>C p.F1642L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67417072; called by muse, mutect2, varscan2
- COL6A3 | c.7153G>T p.D2385Y | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55097365; called by muse, mutect2, varscan2
- COPA | c.1529-6T>G | Splice Region (SNP) | VAF 64/225 reads (28%) | catalogued as COSV54105246; called by muse, mutect2, varscan2
- COPB1 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369909236; called by muse, mutect2, varscan2
- COPB2 | c.2710T>G p.L904V | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as COSV60350640; called by muse, mutect2, varscan2
- COPB2 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1250342666, COSV60813148; called by muse, mutect2, varscan2
- CPA1 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 140/418 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs148329227, COSV50575831; called by muse, varscan2
- CPA1 | c.1235A>G p.E412G | Missense Mutation (SNP) | VAF 32/316 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.259); catalogued as COSV99163275; called by muse, varscan2
- CPAMD8 | c.1664G>A p.R555Q (on ENST00000651564; = p.R508Q on NM_015692.5) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs556626501, COSV52236438; called by muse, mutect2, varscan2
- CPE | c.1113+2T>C p.X371_splice | Splice Site (SNP) | VAF 29/104 reads (28%) | catalogued as COSV68581330; called by muse, mutect2, varscan2
- CPEB2 | c.2288G>A p.R763Q | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as rs974816259, COSV52593181; called by muse, mutect2, varscan2
- CPNE8 | c.845C>A p.S282Y | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100505237; called by muse, mutect2
- CRBN | c.815C>A p.S272Y | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV51640050; called by muse, mutect2, varscan2
- CREB3L4 | c.901C>A p.L301I | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV55132600; called by muse, mutect2, varscan2
- CREM | c.337G>T p.E113* (on ENST00000429130; = p.E64* on NM_001881.3) | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV59766082, COSV59770484; called by muse, mutect2, varscan2
- CRIM1 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.846); catalogued as rs774406061, COSV54859095; called by muse, mutect2, varscan2
- CRIM1 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 69/207 reads (33%) | catalogued as rs1365115540, COSV54867948; called by muse, mutect2, varscan2
- CRPPA | c.1260G>T p.Q420H (on ENST00000407010 / NM_001368197.1; = p.Q370H on NM_001101417.4) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.258); catalogued as COSV67907288; called by muse, mutect2, varscan2
- CRTC3 | c.1594C>A p.H532N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.071); catalogued as COSV51598245, COSV51599293; called by muse, mutect2, varscan2
- CSMD1 | c.10491C>A p.F3497L (on ENST00000520002; = p.F3496L on NM_033225.6) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV59346728; called by mutect2, varscan2
- CSMD3 | c.7534C>A p.L2512I (on ENST00000297405 / NM_001363185.1; = p.L2408I on NM_052900.3) | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52145044, COSV52299134; called by muse, mutect2, varscan2
- CSMD3 | c.5623T>C p.S1875P (on ENST00000297405 / NM_001363185.1; = p.S1771P on NM_052900.3) | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.244); catalogued as COSV99837168; called by muse, mutect2
- CSMD3 | c.4756G>T p.A1586S (on ENST00000297405 / NM_001363185.1; = p.A1482S on NM_052900.3) | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV52167197; called by muse, mutect2, varscan2
- CSNK2A1 | c.485T>C p.V162A | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53936165; called by muse, mutect2, varscan2
- CSPG4 | c.6755C>T p.T2252M | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.826); catalogued as rs778736666, COSV57898168; called by muse, mutect2
- CST1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV59055758; called by muse, mutect2, varscan2
- CTCF | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50467714; called by muse, mutect2, varscan2
- CTSL | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 13/168 reads (8%) | catalogued as COSV100446679; called by muse, mutect2
- CUL2 | c.676T>G p.L226V | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV66079519; called by muse, mutect2, varscan2
- CXCL1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67611532; called by muse, mutect2, varscan2
- CYLC1 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as COSV100254856; called by muse, mutect2
- CYLD | c.863T>G p.F288C | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV61094188, COSV61095920; called by muse, mutect2, varscan2
- CYP3A5 | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as COSV56121381; called by muse, mutect2, varscan2
- DAB2 | c.1106C>T p.S369L | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs769113732, COSV57915680; called by muse, mutect2, varscan2
- DCAF12L1 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as COSV64422190; called by muse, mutect2, varscan2
- DCAF12L2 | c.1277A>C p.E426A | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.09); catalogued as COSV63582864; called by muse, mutect2, varscan2
- DCC | c.1805A>G p.N602S | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59115942; called by muse, mutect2, varscan2
- DCUN1D4 | c.863A>G p.D288G (on ENST00000334635 / NM_001287757.1; = p.D253G on NM_015115.3) | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV58123762; called by muse, mutect2, varscan2
- DDI1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as COSV56375816; called by muse, mutect2, varscan2
- DDI2 | c.352T>G p.S118A | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV60780383; called by muse, mutect2, varscan2
- DDX3X | c.1322C>A p.S441* (on ENST00000399959; = p.S442* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 16/184 reads (9%) | catalogued as COSV101302462; called by muse, mutect2
- DDX4 | c.1169T>G p.F390C | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61755900; called by muse, mutect2, varscan2
- DDX4 | c.1438T>C p.F480L | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV61755908; called by muse, mutect2, varscan2
- DDX43 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs944028999, COSV64836379; called by muse, mutect2
- DECR1 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 10/270 reads (4%) | catalogued as COSV55167094; called by muse, mutect2
- DEFB129 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 72/215 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.011); catalogued as COSV55731705; called by muse, mutect2, varscan2
- DENND1B | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV52468129; called by muse, mutect2, varscan2
- DENND2A | c.2866C>T p.R956W | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs759886035, COSV52050904; called by muse, mutect2, varscan2
- DENND2B | c.3380G>A p.G1127D | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58205509; called by muse, mutect2, varscan2
- DENND4A | c.4295C>T p.A1432V | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1316022150, COSV71266489; called by muse, mutect2, varscan2
- DEUP1 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs757502099, COSV53211877; called by muse, mutect2, varscan2
- DGKK | c.3678G>T p.K1226N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101053066; called by muse, mutect2, varscan2
- DHX57 | c.3363T>G p.Y1121* | Nonsense Mutation (SNP) | VAF 45/149 reads (30%) | catalogued as COSV54887658; called by muse, mutect2, varscan2
- DHX9 | c.3148C>T p.R1050* | Nonsense Mutation (SNP) | VAF 58/184 reads (32%) | catalogued as rs1438628800, COSV62358169; called by muse, mutect2, varscan2
- DIAPH2 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV61260792; called by muse, mutect2, varscan2
- DIAPH3 | c.806G>A p.S269N (on ENST00000400324 / NM_001042517.2; = p.S6N on NM_030932.3) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV57374082; called by muse, mutect2, varscan2
- DIPK2A | c.1048C>A p.L350I | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV100237188; called by muse, mutect2
- DIS3L2 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.131); catalogued as rs1369668644, COSV56058414; called by muse, mutect2, varscan2
- DLGAP2 | c.1889C>T p.T630M | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775275948, COSV70097105; called by muse, mutect2, varscan2
- DNA2 | c.2593G>A p.D865N | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV64429143; called by muse, mutect2, varscan2
- DNA2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.164); catalogued as COSV63063206; called by muse, mutect2, varscan2
- DNAAF1 | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.046); catalogued as COSV100533729, COSV57577928; called by muse, mutect2, varscan2
- DNAH1 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs759820286, COSV70231810; called by muse, mutect2, varscan2
- DNAH10 | c.7927G>T p.D2643Y (on ENST00000409039; = p.D2582Y on NM_207437.3) | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68996671; called by muse, mutect2, varscan2
- DNAH11 | c.5074G>A p.E1692K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs367833062; called by muse, mutect2, varscan2
- DNAH14 | c.757G>T p.D253Y (on ENST00000445597; = p.D126Y on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV64781837; called by muse, mutect2, varscan2
- DNAH2 | c.4381G>T p.D1461Y | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66722165; called by muse, mutect2, varscan2
- DNAH2 | c.8819G>A p.G2940E | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.348); catalogued as COSV66722170; called by muse, mutect2, varscan2
- DNAH3 | c.7817A>C p.K2606T | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV54533656; called by muse, mutect2, varscan2
- DNAH5 | c.13643G>T p.R4548M | Missense Mutation (SNP) | VAF 46/272 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV54237543; called by muse, mutect2, varscan2
- DNAH5 | c.11534G>A p.R3845H | Missense Mutation (SNP) | VAF 89/249 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.608); catalogued as rs1181350575, COSV54210853; called by muse, mutect2, varscan2
- DNAH8 | c.8290-1G>T p.X2764_splice | Splice Site (SNP) | VAF 53/194 reads (27%) | catalogued as COSV59461839; called by muse, mutect2, varscan2
- DNAI3 | c.117T>G p.I39M | Missense Mutation (SNP) | VAF 79/233 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); catalogued as COSV54004104; called by muse, mutect2, varscan2
- DNAJC28 | c.997G>T p.E333* | Nonsense Mutation (SNP) | VAF 43/149 reads (29%) | catalogued as COSV58721896; called by muse, mutect2, varscan2
- DNAJC28 | c.82A>C p.M28L | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV58721906; called by muse, mutect2, varscan2
- DNM3 | c.1564T>G p.S522A | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV62461833; called by muse, mutect2, varscan2
- DOCK3 | c.2765C>T p.S922L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs1273717275, COSV56533165; called by muse, mutect2, varscan2
- DOCK7 | c.6319C>A p.P2107T (on ENST00000635253 / NM_001367561.1; = p.P2076T on NM_033407.3) | Missense Mutation (SNP) | VAF 74/232 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52012597; called by muse, mutect2, varscan2
- DOCK7 | c.2683C>T p.R895* | Nonsense Mutation (SNP) | VAF 10/228 reads (4%) | catalogued as rs1450310137, COSV99223687; called by muse, mutect2
- DOP1B | c.5012A>C p.K1671T | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV67694222; called by muse, varscan2
- DPF3 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as rs1215446338, COSV63501167; called by muse, mutect2, varscan2
- DPYSL3 | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs766945584, COSV58328513; called by muse, mutect2, varscan2
- DRD2 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs200419139, COSV60760017; called by muse, mutect2, varscan2
- DSC3 | c.2309G>T p.G770V | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV64573886; called by muse, mutect2, varscan2
- DSEL | c.2368T>G p.L790V | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV59490878; called by muse, mutect2, varscan2
- DTWD1 | c.448A>G p.K150E | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs1253071857, COSV52072136; called by muse, mutect2, varscan2
- DYM | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 34/196 reads (17%) | catalogued as CM030532, COSV53980071; called by muse, mutect2, varscan2
- DYNC2H1 | c.3678G>T p.E1226D | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.113); catalogued as rs771034508, COSV62099301; called by muse, mutect2, varscan2
- DYRK4 | c.494A>C p.N165T | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV50541402; called by muse, mutect2, varscan2
- ECM1 | c.682A>G p.N228D | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.329); catalogued as COSV100682060; called by muse, mutect2
- EDC4 | c.3709G>A p.A1237T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs745369392, COSV59303216; called by muse, mutect2
- EEF1AKMT4-ECE2 | c.1614G>T p.K538N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as COSV62568872; called by muse, mutect2, varscan2
- EFCAB6 | c.2725T>G p.L909V | Missense Mutation (SNP) | VAF 12/445 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as rs1295538443; called by muse, mutect2
- EFCAB6 | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV53066892; called by muse, mutect2, varscan2
- EFHB | c.1339G>T p.V447L | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55550127; called by muse, mutect2, varscan2
- EHHADH | c.776T>G p.L259R | Missense Mutation (SNP) | VAF 29/383 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99213217; called by muse, mutect2
- EIF4G3 | c.1647C>A p.S549R | Missense Mutation (SNP) | VAF 89/271 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.042); catalogued as COSV51687061; called by muse, mutect2, varscan2
- EIF5 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs1260507504, COSV53685965; called by muse, mutect2, varscan2
- ELAVL2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/239 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV99805321; called by muse, mutect2
- ELOA | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs566963884, COSV69310715; called by muse, mutect2, varscan2
- ELOVL6 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs760345259, COSV56430395; called by muse, varscan2
- EMC7 | c.595A>C p.N199H | Missense Mutation (SNP) | VAF 64/217 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV56628323, COSV56629352; called by muse, mutect2, varscan2
- EMILIN2 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs376887473; called by muse, mutect2, varscan2
- EMSY | c.53G>T p.R18I | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58258746, COSV58262103; called by muse, mutect2, varscan2
- ENAM | c.1332A>C p.K444N | Missense Mutation (SNP) | VAF 126/385 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV68536489; called by muse, mutect2, varscan2
- ENDOD1 | c.1181T>C p.L394S | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99566611; called by muse, mutect2
- ENPEP | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.359); catalogued as COSV54453550; called by muse, mutect2, varscan2
- EPG5 | c.866A>C p.E289A | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV56352310; called by muse, mutect2, varscan2
- EPHA3 | c.2590G>T p.D864Y | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV60714323; called by muse, mutect2, varscan2
- EPX | c.166A>G p.K56E | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99836581; called by muse, mutect2
- ERC2 | c.2568G>T p.Q856H | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99885935; called by muse, mutect2
- ERG28 | c.96T>G p.F32L | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as COSV54038085; called by muse, mutect2, varscan2
- ERI3 | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV60000011; called by muse, mutect2, varscan2
- ERV3-1 | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV51428623; called by muse, mutect2, varscan2
- ESCO1 | c.1493A>C p.N498T | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV52520939; called by muse, mutect2, varscan2
- ETFA | c.986T>C p.I329T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV51211827; called by muse, mutect2, varscan2
- EXOC6B | c.731G>T p.R244M | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.259); catalogued as COSV55562019; called by muse, mutect2, varscan2
- EXT2 | c.1285T>C p.W429R (on ENST00000343631; = p.W462R on NM_000401.3) | Missense Mutation (SNP) | VAF 98/332 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748351664, CM071720, COSV59152212; called by muse, mutect2, varscan2
- EXTL3 | c.677T>C p.V226A | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV55038831; called by muse, mutect2, varscan2
- EYA4 | c.1502A>G p.Y501C (on ENST00000531901 / NM_001301013.1; = p.Y495C on NM_004100.5) | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV62056328; called by muse, mutect2, varscan2
- EZHIP | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.011); catalogued as COSV57955174; called by muse, mutect2
- F13B | c.1855G>T p.D619Y | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV66374679; called by muse, mutect2, varscan2
- F13B | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.049); catalogued as rs533288735, COSV66374683; called by muse, mutect2, varscan2
- F13B | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV66374688; called by muse, mutect2, varscan2
- F2R | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV59929521; called by muse, mutect2, varscan2
- F5 | c.3857C>A p.S1286Y | Missense Mutation (SNP) | VAF 39/720 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.649); catalogued as COSV63121419, COSV63127715; called by muse, mutect2
- FAM102B | c.797T>G p.L266R | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.055); catalogued as COSV100899307; called by muse, mutect2
- FAM120C | c.1490T>C p.V497A | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0.01); catalogued as COSV60260458; called by muse, mutect2, varscan2
- FAM135B | c.3836A>G p.Q1279R | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99424877; called by muse, mutect2
- FAM13C | c.1709G>A p.R570K | Missense Mutation (SNP) | VAF 80/247 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV53251717; called by muse, mutect2, varscan2
- FAM160B1 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs780960997, COSV65088721; called by muse, mutect2, varscan2
- FAM171A1 | c.2081T>C p.M694T | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100968313; called by muse, mutect2
- FAM3B | c.329A>G p.N110S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV63613442; called by muse, mutect2, varscan2
- FAM47A | c.1744G>T p.E582* | Nonsense Mutation (SNP) | VAF 67/214 reads (31%) | catalogued as rs1569241497, COSV60498164; called by muse, mutect2, varscan2
- FAM71A | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54234673, COSV99674676; called by muse, mutect2
- FAM71A | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.665); catalogued as COSV54236267; called by muse, mutect2, varscan2
- FAM90A1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs562876348, COSV56710170; called by muse, mutect2, varscan2
- FANCB | c.2562G>T p.Q854H | Missense Mutation (SNP) | VAF 80/266 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.891); catalogued as COSV60760823; called by muse, mutect2, varscan2
- FANCB | c.1879C>A p.L627I | Missense Mutation (SNP) | VAF 137/411 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0.103); catalogued as COSV60760840; called by muse, mutect2, varscan2
- FANCG | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1195912341, COSV62720249; called by muse, mutect2, varscan2
- FASTKD5 | c.1016A>C p.K339T | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV53907276; called by muse, mutect2, varscan2
- FAT2 | c.7541G>A p.G2514D | Missense Mutation (SNP) | VAF 53/270 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55824082; called by muse, mutect2, varscan2
- FAT2 | c.3494A>C p.D1165A | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55824093; called by muse, mutect2, varscan2
- FAT4 | c.7531A>C p.N2511H | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV58695469; called by muse, mutect2, varscan2
- FBRS | c.526C>T p.R176C (on ENST00000287468; = p.R696C on NM_001105079.3) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs369760361; called by muse, mutect2, varscan2
- FBXL17 | c.1742A>G p.D581G | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV62856226; called by muse, mutect2, varscan2
- FBXO15 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 70/228 reads (31%) | catalogued as COSV54046774; called by muse, mutect2, varscan2
- FCGR2A | c.895G>A p.D299N (on ENST00000271450 / NM_001136219.3; = p.D298N on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.959); catalogued as rs753834370, COSV54839604; called by muse, mutect2, varscan2
- FCHO2 | c.514A>G p.K172E | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV55109942; called by muse, mutect2, varscan2
- FER1L6 | c.1438T>G p.L480V | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as COSV67551280; called by muse, mutect2, varscan2
- FGF7 | c.131T>C p.V44A | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV51066490; called by muse, mutect2, varscan2
- FGF7 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.033); catalogued as COSV51066509, COSV51066694; called by muse, mutect2, varscan2
- FHIT | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs372120945, COSV59309726; called by muse, mutect2, varscan2
- FIGN | c.448A>C p.S150R | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV60769156; called by muse, mutect2, varscan2
- FIGNL1 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63553302; called by muse, mutect2, varscan2
- FIP1L1 | c.476C>A p.S159Y | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60997987; called by muse, mutect2, varscan2
- FKBP5 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV61882645; called by muse, mutect2, varscan2
- FMO1 | c.280T>C p.Y94H | Missense Mutation (SNP) | VAF 82/212 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61446605; called by muse, mutect2, varscan2
- FOCAD | c.3739A>C p.K1247Q | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV58103243; called by muse, mutect2, varscan2
- FOXL1 | c.320T>C p.F107S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57214673; called by muse, mutect2, varscan2
- FRAS1 | c.4007C>T p.S1336L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs746766578, COSV53625416; called by muse, mutect2, varscan2
- FREM1 | c.4327G>A p.E1443K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs1161171266, COSV66521629, COSV66525955; called by muse, mutect2, varscan2
- FREM1 | c.2497A>C p.N833H | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV66526281; called by muse, mutect2, varscan2
- FRMPD2 | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59720112; called by muse, mutect2, varscan2
- FRY | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1322788252, COSV66564878; called by muse, mutect2, varscan2
- FRY | c.4052A>G p.N1351S | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs757871767, COSV66573700; called by muse, mutect2, varscan2
- FSIP1 | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 45/122 reads (37%) | catalogued as COSV52953734; called by muse, mutect2, varscan2
- FSIP2 | c.18073T>G p.F6025V | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV58091622; called by muse, mutect2, varscan2
- FSTL5 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.024); catalogued as rs746283697, COSV60193735; called by muse, mutect2, varscan2
- FTMT | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV58420302; called by muse, mutect2, varscan2
- FTSJ3 | c.1672C>T p.R558W | Missense Mutation (SNP) | VAF 95/295 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs1368914397, COSV63790636; called by muse, mutect2, varscan2
- FYB2 | c.1517A>G p.Y506C | Missense Mutation (SNP) | VAF 120/397 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.298); catalogued as COSV100599598; called by muse, mutect2
- FYCO1 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV56117487; called by muse, mutect2, varscan2
- G2E3 | c.1296G>T p.K432N | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52841463; called by muse, mutect2, varscan2
- G6PC | c.726G>T p.Q242H | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs9905900, COSV99520869; called by muse, mutect2, varscan2
- GAD2 | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 29/102 reads (28%) | catalogued as COSV52162227, COSV99393277; called by muse, mutect2, varscan2
- GALNT7 | c.1148+1G>A p.X383_splice | Splice Site (SNP) | VAF 29/88 reads (33%) | catalogued as rs766682971, COSV53932162; called by muse, mutect2, varscan2
- GANC | c.1759G>A p.D587N | Missense Mutation (SNP) | VAF 33/200 reads (17%) | PolyPhen probably damaging (1); catalogued as rs926918190, COSV58810127; called by muse, varscan2
- GBA3 | c.954G>T p.E318D | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs1387162039, COSV72438352; called by muse, mutect2, varscan2
- GCNT1 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.414); catalogued as rs368814183; called by muse, mutect2, varscan2
- GCOM1 | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as COSV51093293, COSV51095364; called by muse, mutect2, varscan2
- GDAP1L1 | c.636G>T p.K212N | Missense Mutation (SNP) | VAF 23/400 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV100697603; called by muse, mutect2
- GEMIN8 | c.600G>T p.E200D | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as COSV60550322, COSV60550902; called by muse, mutect2, varscan2
- GFOD2 | c.740T>C p.F247S | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV52058795; called by muse, mutect2, varscan2
- GHITM | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as rs1216928773, COSV64538435; called by muse, mutect2, varscan2
- GIPC2 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs138793126, COSV100883246; called by mutect2, varscan2
- GJA5 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.226); catalogued as COSV54783772; called by muse, mutect2
- GK2 | c.1602T>G p.F534L | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV62627649; called by muse, mutect2, varscan2
- GLT8D2 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs367887581; called by muse, mutect2, varscan2
- GLUD2 | c.1332G>T p.K444N | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60151615; called by muse, mutect2
- GNAI1 | c.637C>A p.H213N | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV63523957; called by muse, mutect2, varscan2
- GNPDA1 | c.96G>T p.E32D | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60942122, COSV60942740; called by muse, mutect2, varscan2
- GNPDA2 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV54946353; called by muse, mutect2, varscan2
- GNPDA2 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.722); catalogued as rs761357281, COSV54947418; called by muse, mutect2, varscan2
- GNPTAB | c.3364G>A p.A1122T | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as rs774443381, COSV54777271; called by muse, mutect2
- GPATCH2L | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55049552; called by muse, mutect2, varscan2
- GPHN | c.1159C>T p.R387C (on ENST00000315266 / NM_001377519.1; = p.R420C on NM_020806.5) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59473880; called by muse, mutect2, varscan2
- GPR12 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV67344584; called by muse, mutect2, varscan2
- GPR155 | c.1400C>A p.S467Y | Missense Mutation (SNP) | VAF 79/267 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV55040205; called by muse, mutect2, varscan2
- GPR17 | c.360C>A p.F120L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV55755258; called by muse, mutect2
- GPR22 | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 43/134 reads (32%) | catalogued as rs775834757, COSV51756613; called by muse, mutect2, varscan2
- GPR26 | c.992A>G p.N331S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV99500960; called by muse, mutect2
- GPR34 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59370695; called by muse, mutect2, varscan2
- GPR37 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.274); catalogued as COSV58257760; called by muse, mutect2, varscan2
- GPR52 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs575108337, COSV52307757, COSV99266723; called by muse, mutect2, varscan2
- GRIK3 | c.2756C>A p.P919H | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV100902118; called by muse, mutect2
- GRIN2A | c.3065G>A p.R1022H | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs1349281989, COSV100410263, COSV58043666; called by muse, mutect2, varscan2
- GRIN2A | c.2326G>A p.D776N | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776791010, COSV58019045, COSV58022891; called by muse, mutect2, varscan2
- GRIN2A | c.995A>G p.H332R | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as COSV58043707; called by muse, mutect2, varscan2
- GRK3 | c.281A>C p.K94T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV60798017; called by muse, mutect2, varscan2
- GRM1 | c.13C>A p.L5I | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.043); catalogued as COSV51192712; called by muse, mutect2, varscan2
- GRM1 | c.1062C>A p.F354L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV51129025, COSV51193045; called by muse, mutect2, varscan2
- GRXCR1 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754691699, COSV67670250; called by muse, mutect2, varscan2
- GRXCR2 | c.143A>G p.E48G | Missense Mutation (SNP) | VAF 80/243 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV65061501; called by muse, mutect2, varscan2
- GSDME | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61652298; called by muse, mutect2, varscan2
- GTF2E2 | c.547A>G p.K183E | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.225); catalogued as rs760282859, COSV63478708; called by muse, mutect2, varscan2
- GTF3C3 | c.2567G>A p.R856Q | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.212); catalogued as rs763347898, COSV55833131; called by muse, mutect2, varscan2
- GUCA1C | c.112C>A p.H38N | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV51724597; called by muse, mutect2, varscan2
- GUCY2F | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV54305241, COSV54307732; called by muse, mutect2, varscan2
- GXYLT1 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs76555438, COSV55138876; called by muse, mutect2, varscan2
- HAO2 | c.1027C>T p.R343* | Nonsense Mutation (SNP) | VAF 30/196 reads (15%) | catalogued as rs764148838, COSV58038827; called by muse, mutect2, varscan2
- HCK | c.1235C>A p.T412K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV52944756; called by muse, mutect2, varscan2
- HDAC3 | c.1041G>T p.E347D | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV59496612; called by muse, mutect2, varscan2
- HEATR9 | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 29/733 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs371570312; called by muse, mutect2
- HECTD1 | c.1620A>G p.I540M | Missense Mutation (SNP) | VAF 91/261 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV67947582; called by muse, mutect2, varscan2
- HECTD4 | c.4039T>G p.F1347V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.197); catalogued as COSV61180411; called by muse, mutect2, varscan2
- HELQ | c.1162C>A p.L388I | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55024119, COSV55026208; called by muse, mutect2, varscan2
- HENMT1 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 36/121 reads (30%) | catalogued as COSV64230414; called by muse, mutect2, varscan2
- HEPACAM2 | c.109C>T p.P37S (on ENST00000394468 / NM_001039372.4; = p.P25S on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs750096728, COSV59061736; called by muse, mutect2, varscan2
- HEPHL1 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV59893768; called by muse, mutect2, varscan2
- HEPHL1 | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV59893776, COSV59896274, COSV59896955; called by muse, mutect2, varscan2
- HERC2 | c.5491G>T p.D1831Y | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV55334301; called by muse, mutect2, varscan2
- HIBADH | c.964G>T p.D322Y | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99607238; called by muse, mutect2
- HIPK1 | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as rs370415621, COSV61245810; called by muse, mutect2, varscan2
- HIVEP2 | c.3758C>T p.S1253L | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs1242609751, COSV50023861; called by muse, mutect2, varscan2
- HK2 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 129/349 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.031); catalogued as rs1163770214, COSV51877011; called by muse, mutect2, varscan2
- HLA-DMA | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV66385920; called by muse, mutect2, varscan2
- HOXA7 | c.550A>G p.K184E | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54218326; called by muse, mutect2, varscan2
- HOXC5 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as rs1432556399, COSV54537503; called by muse, mutect2, varscan2
- HPS5 | c.3279G>T p.E1093D (on ENST00000349215 / NM_181507.2; = p.E979D on NM_007216.4) | Missense Mutation (SNP) | VAF 9/224 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.295); catalogued as COSV61687191; called by muse, mutect2
- HRNR | c.495T>G p.F165L | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64260144; called by muse, mutect2, varscan2
- HS3ST5 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 19/60 reads (32%) | catalogued as COSV57138038; called by muse, mutect2, varscan2
- HSP90AB1 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 107/340 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs1166963293, COSV62335472; called by muse, mutect2, varscan2
- HTATSF1 | c.1459G>T p.E487* | Nonsense Mutation (SNP) | VAF 90/252 reads (36%) | catalogued as COSV54479862; called by muse, mutect2, varscan2
- HTR2A | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.42); catalogued as rs1428173433, COSV66326797; called by muse, mutect2, varscan2
- HTR2A | c.136A>G p.T46A | Missense Mutation (SNP) | VAF 81/255 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV66327752; called by muse, mutect2, varscan2
- HTR3B | c.214-1G>T p.X72_splice | Splice Site (SNP) | VAF 24/78 reads (31%) | catalogued as COSV52746154; called by muse, mutect2, varscan2
- HTR3E | c.304T>G p.W102G (on ENST00000415389 / NM_001256613.1; = p.W117G on NM_182589.2) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58947681; called by muse, mutect2, varscan2
- HTR5A | c.397A>G p.T133A | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0.046); catalogued as COSV55284847; called by muse, mutect2, varscan2
- HYLS1 | c.55C>T p.R19* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as rs143088549; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HYOU1 | c.2378T>C p.M793T | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.048); catalogued as COSV68216557; called by muse, mutect2, varscan2
- IFNA14 | c.538A>C p.N180H | Missense Mutation (SNP) | VAF 179/613 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); catalogued as COSV66516256; called by muse, mutect2, varscan2
- IFNG | c.263G>A p.S88N | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1285316047, COSV57491590; called by muse, mutect2, varscan2
- IFNK | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 51/168 reads (30%) | catalogued as COSV51783454; called by muse, mutect2, varscan2
- IFT88 | c.768A>C p.R256S (on ENST00000319980 / NM_001318493.2; = p.R247S on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.251); catalogued as COSV60674951; called by muse, mutect2, varscan2
- IFTAP | c.238C>A p.L80I | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.056); catalogued as COSV57558530; called by muse, mutect2, varscan2
- IGBP1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.069); catalogued as COSV60556758; called by muse, mutect2, varscan2
- IGF2BP1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs747039976, COSV51733345; called by muse, mutect2, varscan2
- IGF2R | c.1211+2T>C p.X404_splice | Splice Site (SNP) | VAF 41/117 reads (35%) | catalogued as COSV63628729; called by muse, mutect2, varscan2
- IGFBP1 | c.512A>T p.K171I | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.746); catalogued as COSV51875014; called by muse, mutect2, varscan2
- IGKV6D-41 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372242278; called by muse, mutect2, varscan2
- IGSF1 | c.2752C>T p.R918W | Missense Mutation (SNP) | VAF 23/241 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.536); catalogued as rs201712796, COSV63836956; called by muse, mutect2
- IGSF10 | c.6947G>A p.R2316Q | Missense Mutation (SNP) | VAF 49/236 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.527); catalogued as rs765361967, COSV56367113; called by muse, varscan2
- IGSF10 | c.6881A>C p.K2294T | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.505); catalogued as COSV56385945; called by muse, varscan2
- IL12RB2 | c.62T>C p.I21T | Missense Mutation (SNP) | VAF 82/230 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV52024803; called by muse, mutect2, varscan2
- IL12RB2 | c.151T>C p.C51R | Missense Mutation (SNP) | VAF 120/382 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52024811; called by muse, mutect2, varscan2
- IL17A | c.107C>A p.S36Y | Missense Mutation (SNP) | VAF 18/678 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV60685413; called by muse, mutect2
- IL1RAPL2 | c.1918A>G p.T640A | Missense Mutation (SNP) | VAF 91/255 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.038); catalogued as COSV61166906; called by muse, mutect2, varscan2
- IL23R | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV100724792; called by muse, mutect2
- IL2RG | c.501A>T p.E167D | Missense Mutation (SNP) | VAF 70/275 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV52149310; called by muse, mutect2, varscan2
- IL36B | c.399G>T p.K133N | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as COSV52087449, COSV52088998; called by muse, mutect2, varscan2
- IMPA1 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767783535, COSV99809003; called by muse, mutect2
- INTS6L | c.2380C>T p.R794* | Nonsense Mutation (SNP) | VAF 45/138 reads (33%) | catalogued as COSV66085067; called by muse, mutect2, varscan2
- IPO11 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 10/113 reads (9%) | catalogued as COSV57571881; called by muse, mutect2
- IPO4 | c.2622G>T p.E874D | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.042); catalogued as COSV61017308; called by muse, mutect2
- IPO8 | c.1966C>A p.L656I | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs748079950, COSV56243368, COSV56244960; called by muse, mutect2, varscan2
- IQCD | c.707G>A p.R236K | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV55320735, COSV55322327; called by muse, mutect2, varscan2
- IQGAP1 | c.2297G>A p.R766Q | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs980602514, COSV51587955; called by muse, mutect2, varscan2
- IQGAP2 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as rs201127307, COSV104387320, COSV57176803; called by muse, mutect2, varscan2
- IRS4 | c.3089C>T p.A1030V | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1016961545, COSV64534717; called by muse, mutect2, varscan2
- ITGA5 | c.1694C>A p.S565Y | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); catalogued as COSV53219211; called by muse, mutect2, varscan2
- ITIH1 | c.1014A>C p.Q338H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as COSV56256464, COSV56257872; called by muse, mutect2, varscan2
- ITIH6 | c.3835C>A p.L1279M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54491096; called by muse, mutect2, varscan2
- ITPR2 | c.7297C>A p.P2433T | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV67272174; called by muse, mutect2, varscan2
- JADE3 | c.657C>A p.F219L | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54468209; called by muse, mutect2, varscan2
- JAG1 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 56/210 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as rs1286744339, COSV54756484; called by muse, varscan2
- JAM2 | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 30/78 reads (38%) | catalogued as COSV57255578; called by muse, mutect2, varscan2
- JAML | c.770G>A p.R257Q (on ENST00000356289 / NM_001098526.2; = p.R247Q on NM_153206.3) | Missense Mutation (SNP) | VAF 222/684 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as rs769308889, COSV52627078; called by muse, mutect2, varscan2
- JMJD1C | c.3425C>A p.S1142Y | Missense Mutation (SNP) | VAF 13/265 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100550641; called by muse, mutect2
- JMY | c.1843C>T p.R615W | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs561913921, COSV68661552; called by muse, mutect2, varscan2
- JMY | c.2050C>T p.R684* | Nonsense Mutation (SNP) | VAF 115/347 reads (33%) | catalogued as rs757801796, COSV68659765; called by muse, mutect2, varscan2
- KAT2B | c.2027G>T p.R676I | Missense Mutation (SNP) | VAF 25/442 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV55428171; called by muse, mutect2
- KCNA10 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764773118, COSV63904457; called by muse, mutect2, varscan2
- KCNH1 | c.1036A>C p.I346L (on ENST00000271751 / NM_172362.3; = p.I319L on NM_002238.4) | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.107); catalogued as COSV55090104; called by muse, mutect2, varscan2
- KCNH5 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs148002630, COSV59766398; called by muse, mutect2, varscan2
- KCNJ1 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 61/191 reads (32%) | catalogued as COSV60662207; called by muse, mutect2, varscan2
- KCNJ3 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 51/165 reads (31%) | catalogued as COSV54539457, COSV54547338; called by muse, mutect2, varscan2
- KCNJ8 | c.1213C>T p.L405F | Missense Mutation (SNP) | VAF 53/288 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1314690536, COSV53717249; called by muse, mutect2, varscan2
- KCNQ5 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as rs920140431, COSV59649400, COSV59676282; called by muse, mutect2, varscan2
- KCNQ5 | c.1661C>A p.S554Y | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59648592, COSV59659658; called by muse, mutect2, varscan2
- KCNU1 | c.2259C>A p.F753L | Missense Mutation (SNP) | VAF 123/364 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as COSV67757728; called by muse, mutect2, varscan2
- KCTD7 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.245); catalogued as rs772773351, COSV51876457; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM2A | c.3181C>T p.R1061C | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58188551; called by muse, mutect2
- KDM5A | c.4877T>C p.V1626A | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101238917; called by muse, mutect2
- KHDRBS2 | c.317C>A p.S106* | Nonsense Mutation (SNP) | VAF 63/248 reads (25%) | catalogued as COSV55427305, COSV55470250; called by muse, mutect2, varscan2
- KIAA0319 | c.3017G>T p.R1006I | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1467932870, COSV100985637; called by muse, mutect2
- KIAA0408 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1257544970, COSV100846960; called by muse, mutect2
- KIAA0753 | c.2444A>C p.Q815P | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV63816883, COSV63818007; called by muse, mutect2, varscan2
- KIAA1109 | c.4700C>A p.S1567Y | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.229); catalogued as COSV52681682; called by muse, mutect2, varscan2
- KIAA1549L | c.1480G>A p.D494N (on ENST00000321505; = p.D791N on NM_012194.3) | Missense Mutation (SNP) | VAF 80/277 reads (29%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV55776892; called by muse, mutect2, varscan2
- KIAA1549L | c.5434G>A p.D1812N (on ENST00000321505; = p.D2109N on NM_012194.3) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as rs759039531, COSV58592586; called by muse, mutect2, varscan2
- KIF14 | c.194G>T p.R65I | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV66262552; called by muse, mutect2, varscan2
- KIF16B | c.3526A>G p.N1176D | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.036); catalogued as COSV61709198; called by muse, mutect2, varscan2
- KIF20B | c.3059A>C p.N1020T (on ENST00000371728 / NM_001284259.2; = p.N980T on NM_016195.4) | Missense Mutation (SNP) | VAF 78/252 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as COSV53310573; called by muse, mutect2, varscan2
- KIF27 | c.2116G>T p.E706* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as COSV52826927; called by muse, mutect2, varscan2
- KIF4B | c.392A>G p.D131G | Missense Mutation (SNP) | VAF 93/255 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as COSV70530277; called by muse, mutect2, varscan2
- KIF5B | c.824T>C p.V275A | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV56654193; called by muse, mutect2, varscan2
- KIF9 | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV55521127; called by muse, mutect2, varscan2
- KIFBP | c.1714T>C p.S572P | Missense Mutation (SNP) | VAF 13/226 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100741395; called by muse, mutect2
- KIR3DL2 | c.1120G>T p.D374Y | Missense Mutation (SNP) | VAF 140/544 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54393733, COSV99551925; called by muse, varscan2
- KLHDC8A | c.782C>A p.S261* | Nonsense Mutation (SNP) | VAF 29/96 reads (30%) | catalogued as rs766875332, COSV65679013, COSV65679062; called by muse, mutect2, varscan2
- KLHL13 | c.1169T>G p.F390C | Missense Mutation (SNP) | VAF 11/195 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99451810; called by muse, mutect2
- KLHL15 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.382); catalogued as rs1486371427, COSV100044238; called by muse, mutect2
- KLHL15 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 93/498 reads (19%) | catalogued as COSV60141209; called by muse, mutect2, varscan2
- KLHL28 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1207081442, COSV100753148; called by muse, varscan2
- KLHL28 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs753907485, COSV61888716; called by muse, varscan2
- KLHL5 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767326522, COSV54671389, COSV54672017; called by muse, mutect2, varscan2
- KMT2A | c.7478C>T p.S2493F | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.172); catalogued as COSV63288865; called by muse, mutect2, varscan2
- KMT2D | c.16502G>A p.R5501Q | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56412534; called by muse, mutect2, varscan2
- KPNB1 | c.2318T>C p.V773A | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as COSV51598479; called by muse, mutect2, varscan2
- KPRP | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as rs144964533; called by muse, mutect2, varscan2
- KPTN | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.454); catalogued as rs776547634, COSV57644921; called by muse, mutect2, varscan2
- KRT85 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV57736893; called by muse, mutect2, varscan2
- KRTAP11-1 | c.440T>C p.V147A | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV60094266; called by muse, mutect2, varscan2
- KYAT3 | c.261G>T p.K87N | Missense Mutation (SNP) | VAF 77/189 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as COSV53101044; called by muse, mutect2, varscan2
- LAMA2 | c.4828T>C p.Y1610H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV70351305; called by muse, mutect2, varscan2
- LAMA3 | c.3272A>G p.H1091R | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV58072715; called by muse, mutect2, varscan2
- LARP1B | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs761810288, COSV52796406; called by muse, mutect2, varscan2
- LCA5 | c.1876T>G p.S626A | Missense Mutation (SNP) | VAF 88/276 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV63972003; called by muse, mutect2, varscan2
- LCA5L | c.1471G>T p.E491* | Nonsense Mutation (SNP) | VAF 24/97 reads (25%) | catalogued as COSV55744918, COSV55746264; called by muse, mutect2, varscan2
- LCT | c.2527G>T p.E843* | Nonsense Mutation (SNP) | VAF 46/127 reads (36%) | catalogued as COSV51549194; called by muse, mutect2, varscan2
- LDB3 | c.1815C>A p.F605L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.444); catalogued as COSV53939733; called by muse, mutect2, varscan2
- LGALS9C | c.44T>C p.V15A | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as COSV60196124; called by muse, mutect2, varscan2
- LHCGR | c.1906C>A p.L636I | Missense Mutation (SNP) | VAF 147/461 reads (32%) | SIFT tolerated (1); PolyPhen probably damaging (0.984); catalogued as COSV54299317, COSV54299540; called by muse, mutect2, varscan2
- LHFPL6 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as rs758624379, COSV65447212; called by muse, mutect2, varscan2
- LHX4 | c.519G>T p.K173N | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV55374542; called by muse, mutect2
- LIMS2 | c.898G>A p.D300N (on ENST00000355119 / NM_001161403.3; = p.D324N on NM_017980.4) | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61443712; called by muse, mutect2, varscan2
- LIN9 | c.712C>T p.R238W (on ENST00000366808 / NM_001270410.2; = p.R183W on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60243760, COSV60246891; called by muse, mutect2, varscan2
- LINGO2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs770649517, COSV58061559; called by muse, mutect2, varscan2
- LIPA | c.229+1G>A p.X77_splice | Splice Site (SNP) | VAF 35/129 reads (27%) | catalogued as rs201104126, CS122002, COSV51079675; called by muse, mutect2, varscan2
- LMBRD2 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as rs762650524, COSV56948565; called by muse, mutect2, varscan2
- LMNTD1 | c.387C>A p.Y129* | Nonsense Mutation (SNP) | VAF 62/197 reads (31%) | catalogued as COSV51448636; called by muse, mutect2, varscan2
- LRP12 | c.1034C>A p.S345Y | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV52630954, COSV52633872; called by muse, mutect2, varscan2
- LRP1B | c.5987A>G p.D1996G | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV67196679, COSV67246011; called by muse, mutect2, varscan2
- LRP2 | c.12187C>T p.R4063* | Nonsense Mutation (SNP) | VAF 53/150 reads (35%) | catalogued as rs762645702, COSV55561498; called by muse, mutect2, varscan2
- LRP2 | c.11126G>A p.S3709N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1314969154, COSV55561508; called by muse, mutect2, varscan2
- LRRC6 | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 58/174 reads (33%) | catalogued as rs779571778, COSV51544348; called by muse, mutect2, varscan2
- LRRC8C | c.1639C>A p.L547I | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV64999444; called by muse, mutect2, varscan2
- LRRFIP1 | c.1710G>T p.K570N (on ENST00000392000 / NM_001137552.2; = p.K546N on NM_004735.4) | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV55250433, COSV99790892; called by muse, mutect2
- LRRIQ1 | c.3881T>G p.L1294* | Nonsense Mutation (SNP) | VAF 83/275 reads (30%) | catalogued as COSV67833950; called by muse, mutect2, varscan2
- LSAMP | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs1327300651, COSV61274929; called by muse, mutect2, varscan2
- LTN1 | c.1659A>C p.E553D | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.096); catalogued as COSV63734399; called by muse, mutect2, varscan2
- LTV1 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 73/251 reads (29%) | catalogued as rs201919461; called by muse, mutect2, varscan2
- LYST | c.6946C>A p.L2316I | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV67709959, COSV67711839; called by muse, mutect2, varscan2
- MAB21L2 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV58262595; called by muse, mutect2, varscan2
- MAEL | c.1290C>A p.F430L | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV63305624, COSV63305924; called by muse, mutect2, varscan2
- MAGEB10 | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63311820; called by muse, mutect2, varscan2
- MAGEB2 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 29/64 reads (45%) | catalogued as COSV66781132; called by muse, mutect2, varscan2
- MAML3 | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100505225; called by muse, mutect2
- MAN2A1 | c.2993C>T p.S998L | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as rs772603547, COSV54849899; called by muse, mutect2, varscan2
- MAP10 | c.158T>G p.L53R | Missense Mutation (SNP) | VAF 67/236 reads (28%) | PolyPhen benign (0.402); catalogued as COSV69364147; called by muse, mutect2, varscan2
- MAP1A | c.5176G>A p.E1726K | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV55810560; called by muse, mutect2, varscan2
- MAP3K1 | c.1363A>C p.S455R | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68125152; called by muse, mutect2, varscan2
- MAP3K19 | c.3138G>T p.K1046N | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV59640482; called by muse, mutect2, varscan2
- MAP7D2 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.323); catalogued as COSV65525688; called by muse, mutect2, varscan2
- MAPK8 | c.303T>G p.F101L | Missense Mutation (SNP) | VAF 109/320 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV64410038; called by muse, mutect2, varscan2
- MARCHF11 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1383446854, COSV100197580, COSV60131250; called by muse, varscan2
- MARVELD2 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV57780844; called by muse, mutect2, varscan2
- MASP1 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 71/239 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs774669955, COSV51459785; called by muse, mutect2, varscan2
- MCF2 | c.2121G>T p.K707N | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100644844; called by muse, mutect2
- MCF2L2 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.133); catalogued as rs761107247, COSV61053454; called by muse, mutect2, varscan2
- MCMDC2 | c.1047A>G p.I349M | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV58037752; called by muse, mutect2, varscan2
- MCUR1 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as rs145895773; called by muse, mutect2, varscan2
- MDM1 | c.560G>T p.R187I | Missense Mutation (SNP) | VAF 153/451 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV57444652; called by muse, mutect2, varscan2
- MECR | c.353A>G p.N118S | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs746554300, COSV55286248; called by muse, mutect2, varscan2
- MED12 | c.3830T>C p.V1277A | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV61346288; called by muse, mutect2, varscan2
- MED13L | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs773315749, COSV56116702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MED17 | c.671T>G p.V224G | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52601863; called by muse, mutect2, varscan2
- MEIS2 | c.799G>A p.D267N (on ENST00000561208 / NM_170675.5; = p.D254N on NM_002399.3) | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as COSV54937494; called by muse, mutect2
- MEOX2 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100012269; called by muse, mutect2
- MEP1B | c.2069G>A p.R690Q | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.014); catalogued as rs759192471, COSV52495941; called by muse, mutect2, varscan2
- MFF | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs201498602, COSV100449274; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MFSD9 | c.1414A>G p.K472E | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51494637; called by muse, mutect2, varscan2
- MGAM | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs779098977, COSV71884967; called by muse, mutect2, varscan2
- MIA2 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 7/175 reads (4%) | catalogued as COSV99696902; called by muse, mutect2
- MINDY3 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 74/251 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs776784319, COSV53219143; called by muse, mutect2, varscan2
- MIOS | c.189G>T p.M63I | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100402828; called by muse, mutect2
- MITD1 | c.194T>A p.I65N | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99175570; called by muse, mutect2, varscan2
- MLH3 | c.2935G>T p.V979F | Missense Mutation (SNP) | VAF 85/249 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as rs1566602843, COSV53156731; called by muse, mutect2, varscan2
- MLYCD | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376453144; called by muse, mutect2, varscan2
- MMP13 | c.1319A>G p.Y440C | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52824626; called by muse, mutect2, varscan2
- MMRN1 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.603); catalogued as COSV53339619, COSV53340226; called by muse, mutect2, varscan2
- MMUT | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as rs774457503, CM128365, COSV51272824; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MOB1B | c.408T>G p.I136M | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.477); catalogued as COSV58674413; called by muse, mutect2, varscan2
- MOGAT2 | c.596T>C p.F199S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV52220611; called by muse, mutect2, varscan2
- MORC1 | c.2485C>T p.L829F | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV99226541; called by muse, mutect2
- MPDZ | c.3101G>A p.R1034Q | Missense Mutation (SNP) | VAF 145/478 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376187489; called by muse, mutect2, varscan2
- MROH2B | c.4011G>T p.K1337N | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs757290164, COSV68186494; called by muse, mutect2, varscan2
- MSH4 | c.2729G>A p.R910Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs777072562, COSV54196382; called by muse, mutect2, varscan2
- MSN | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.292); catalogued as COSV64304658; called by muse, mutect2, varscan2
- MSR1 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 33/70 reads (47%) | catalogued as rs762856785, COSV50518319; called by muse, mutect2, varscan2
- MTF2 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); catalogued as rs759180756, COSV64769675; called by muse, mutect2, varscan2
- MTMR9 | c.398T>C p.F133S | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99644371; called by muse, mutect2
- MUC3A | c.6977C>A p.S2326Y | Missense Mutation (SNP) | VAF 67/497 reads (13%) | SIFT tolerated, low confidence (0.24); catalogued as COSV60219566; called by muse, mutect2, varscan2
- MUC5B | c.9496G>T p.E3166* | Nonsense Mutation (SNP) | VAF 26/64 reads (41%) | catalogued as COSV71593927; called by muse, mutect2, varscan2
- MUC5B | c.12934A>G p.T4312A | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.81); PolyPhen benign (0.031); catalogued as COSV71593930; called by muse, mutect2, varscan2
- MUC7 | c.699del p.T234Pfs*36 | Frame Shift Del (DEL) | VAF 106/487 reads (22%) | catalogued as COSV59219274; called by muse*, mutect2
- MXRA5 | c.4090G>A p.E1364K | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs1310840774, COSV54233872, COSV54240240; called by muse, mutect2, varscan2
- MXRA5 | c.576G>T p.E192D | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV54241544; called by muse, mutect2, varscan2
- MYB | c.187T>C p.W63R | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57199620; called by muse, mutect2, varscan2
- MYBPC1 | c.1345G>T p.E449* (on ENST00000550270 / NM_206820.2; = p.E474* on NM_002465.4) | Nonsense Mutation (SNP) | VAF 123/355 reads (35%) | catalogued as COSV62252081, COSV62256429; called by muse, mutect2
- MYF6 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV57351008; called by muse, mutect2, varscan2
- MYH1 | c.4997G>A p.R1666Q | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.265); catalogued as rs769510752, COSV56845448, COSV56849245; called by muse, mutect2, varscan2
- MYH1 | c.4620A>C p.E1540D | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV56852146; called by muse, mutect2, varscan2
- MYH1 | c.1780G>T p.A594S | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV56852155; called by muse, mutect2, varscan2
- MYH15 | c.2428C>T p.R810* | Nonsense Mutation (SNP) | VAF 44/105 reads (42%) | catalogued as rs201762535; called by muse, mutect2, varscan2
- MYLK | c.5242A>G p.T1748A | Missense Mutation (SNP) | VAF 64/229 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60614704; called by muse, mutect2, varscan2
- MYLK3 | c.1795G>A p.D599N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs780286175, COSV67365112; called by muse, varscan2
- MYLK4 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs752979205, COSV51141460; called by muse, mutect2, varscan2
- MYNN | c.462G>T p.E154D | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.899); catalogued as COSV62991082; called by muse, mutect2, varscan2
- MYO18B | c.7574A>G p.K2525R | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV59140412; called by muse, mutect2, varscan2
- MYO1B | c.1239A>C p.Q413H | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58433925; called by muse, mutect2, varscan2
- MYO9A | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61853764; called by muse, mutect2, varscan2
- MYOCD | c.2438C>T p.S813F | Missense Mutation (SNP) | VAF 25/303 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV100590917; called by muse, mutect2
- MYOM1 | c.3673G>A p.D1225N | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.433); catalogued as COSV55295422; called by muse, mutect2, varscan2
- MYOM2 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.704); catalogued as rs758822676, COSV100037002, COSV50732411; called by muse, mutect2, varscan2
- NAA25 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 22/67 reads (33%) | catalogued as COSV55706059, COSV99927186; called by muse, mutect2, varscan2
- NANS | c.1016T>C p.V339A | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.287); catalogued as COSV52964496; called by muse, mutect2, varscan2
- NAP1L2 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 16/323 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV65172298, COSV65173210; called by muse, mutect2
- NAP1L2 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 112/314 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65172605, COSV65172728; called by muse, mutect2, varscan2
- NAP1L4 | c.307T>G p.F103V | Missense Mutation (SNP) | VAF 63/209 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV65881533; called by muse, mutect2, varscan2
- NAPG | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59797651; called by muse, varscan2
- NAT10 | c.605A>G p.D202G | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57664958; called by muse, mutect2, varscan2
- NBEA | c.3362del p.N1121Mfs*9 | Frame Shift Del (DEL) | VAF 14/122 reads (11%) | catalogued as rs763376147; called by mutect2, varscan2
- NCBP1 | c.860T>C p.V287A | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV64317042; called by muse, mutect2, varscan2
- NCF2 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); catalogued as COSV100838908; called by muse, mutect2
- NCKAP5 | c.2236G>T p.D746Y | Missense Mutation (SNP) | VAF 77/237 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1417667146, COSV58457457; called by muse, mutect2, varscan2
- NCOA6 | c.5252C>A p.S1751Y | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as COSV62865506; called by muse, mutect2, varscan2
- NCOA6 | c.1604C>T p.S535L | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.173); catalogued as rs755268427, COSV62863226; called by muse, mutect2, varscan2
- NDRG3 | c.444+2T>C p.X148_splice (on ENST00000349004 / NM_032013.4; = p.X136_splice on NM_022477.4) | Splice Site (SNP) | VAF 45/122 reads (37%) | catalogued as COSV62422538; called by muse, mutect2, varscan2
- NDST3 | c.388C>A p.L130I | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.424); catalogued as rs1202146328, COSV56623107; called by muse, mutect2, varscan2
- NDUFAF6 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 43/124 reads (35%) | catalogued as rs753873681, COSV54406997; called by muse, mutect2, varscan2
- NDUFC2 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 124/368 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs147426758; called by muse, mutect2, varscan2
- NEB | c.10099A>C p.N3367H | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV51433491; called by muse, mutect2, varscan2
- NEB | c.417G>T p.M139I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV51433514; called by muse, mutect2
- NECAB1 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 4/8 reads (50%) | catalogued as COSV70241653; called by muse, mutect2, varscan2
- NEK11 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as rs767453779, COSV63578843; called by muse, varscan2
- NEK4 | c.2020C>A p.H674N | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV51781454; called by muse, mutect2, varscan2
- NEK4 | c.1096A>C p.N366H | Missense Mutation (SNP) | VAF 224/742 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV51781463; called by muse, mutect2, varscan2
- NEK4 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 77/187 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.086); catalogued as rs1338917509, COSV51781476; called by muse, mutect2, varscan2
- NELL2 | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 74/205 reads (36%) | catalogued as COSV61579164; called by muse, mutect2, varscan2
- NES | c.2401A>G p.N801D | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV63961708; called by muse, mutect2, varscan2
- NF1 | c.5177T>G p.L1726R (on ENST00000358273 / NM_001042492.3; = p.L1705R on NM_000267.3) | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55986447; called by muse, mutect2, varscan2
- NFASC | c.3359T>C p.L1120P (on ENST00000339876 / NM_001378329.1; = p.L1049P on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58371372; called by muse, mutect2, varscan2
- NHSL2 | c.1066C>G p.P356A (on ENST00000510661; = p.P722A on NM_001013627.2) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV65454058; called by muse, mutect2, varscan2
- NIBAN1 | c.686C>A p.S229Y | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV62286102; called by muse, mutect2, varscan2
- NID2 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV53499217; called by muse, mutect2, varscan2
- NIPA2 | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 54/263 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV61682833; called by muse, mutect2, varscan2
- NLRP1 | c.1661A>G p.Y554C | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV52570914; called by muse, mutect2, varscan2
- NLRP12 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.777); catalogued as COSV60750211; called by muse, mutect2, varscan2
- NLRP14 | c.640T>C p.F214L | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55069300; called by muse, mutect2, varscan2
- NMRAL1 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.382); catalogued as rs149409840, COSV52060040; called by muse, mutect2, varscan2
- NNT | c.1979C>A p.A660E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV52926882; called by muse, mutect2, varscan2
- NOA1 | c.1508A>C p.E503A | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV99950577; called by muse, mutect2
- NOL4 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 134/389 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as rs757148536, COSV52338009; called by muse, mutect2, varscan2
- NOL9 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs754182931, COSV60228139; called by muse, mutect2, varscan2
- NOP58 | c.1522A>G p.T508A | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs34523815, COSV51897473; called by muse, mutect2, varscan2
- NOTCH4 | c.3653C>A p.S1218Y | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as COSV66682085; called by muse, mutect2, varscan2
- NOX3 | c.94T>C p.Y32H | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99343285; called by muse, mutect2
- NPAS4 | c.573C>A p.F191L | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.043); catalogued as COSV60651414; called by muse, mutect2, varscan2
- NPL | c.875T>G p.F292C | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.956); catalogued as COSV51124997; called by muse, mutect2, varscan2
- NPS | c.240A>C p.K80N | Missense Mutation (SNP) | VAF 67/243 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV101219371, COSV67690699; called by muse, mutect2, varscan2
- NPY4R | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.139); catalogued as COSV65398446; called by muse, mutect2, varscan2
- NR1H3 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as rs776139734, COSV68008601; called by muse, mutect2, varscan2
- NR2F2 | c.544A>C p.I182L | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV67683850; called by muse, mutect2, varscan2
- NRCAM | c.3084C>A p.F1028L (on ENST00000379028 / NM_001371124.1; = p.F1012L on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61036276; called by muse, mutect2, varscan2
1,018 further variants in this file (610 protein-altering or splice-affecting, 361 silent, 47 other) are not listed here.
